Gene-level copy-number profile of tumor specimen TCGA-DD-A1EF-01A from TCGA case TCGA-DD-A1EF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.9 years (21,165 days).
Specimen TCGA-DD-A1EF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c6c35956-54a9-4dae-9bcb-d737b5e977b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A1EF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f687dc44-2adb-43a7-b55a-8b1083995b1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,028; copy number 2: 31,647; copy number 3: 14,506; copy number 4: 7,791; copy number 5: 673; copy number 6: 1,171; copy number 8: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A1EF-01A-11D-A12Y-01): tumor purity 0.45, ploidy 4.68, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,845 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,064,533–207,879,115, 124 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:202,073,255–202,205,188, 1 gene, copy number 5 (within-gene range 3–5): KIAA2012.
- chr2:202,137,570–206,162,928, 81 genes, copy number 5 (broad region; genes not listed).
- chr6:2,987,967–3,057,357, 9 genes, copy number 6: LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–8 (broad region; genes not listed).
- chr12:56,521,820–58,813,060, 94 genes, copy number 6 (broad region; genes not listed).
- chr20:61,267,525–61,370,855, 2 genes, copy number 5: AL365229.1, BX640515.1.

Autosomal genes at a single copy (total copy number 1): 1,607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
